Somatic mutation profile of cancer-model specimen HCM-CSHL-0161-C18-85B (3D Organoid; aliquot HCM-CSHL-0161-C18-85B-01D-A78T-36), derived from the primary tumor of HCMI case HCM-CSHL-0161-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: GB; Age at diagnosis: 74.5 years (27,209 days).
Specimen HCM-CSHL-0161-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3821d018-0ef3-4211-9e90-8804166f5c76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0161-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0161-C18-11A-11D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dda1a1d-227c-4363-80b0-0292bf1981d2

The open-access MAF lists 219 somatic variants for this specimen: 160 protein-altering or splice-affecting, 46 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 46, Nonsense Mutation 11, Frame Shift Del 7, Intron 5, 5'UTR 4, Frame Shift Ins 4, 3'UTR 3, Splice Region 2, In Frame Del 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1973G>A p.R658Q (on ENST00000281708 / NM_001349798.2; = p.R578Q on NM_018315.5) | Missense Mutation (SNP) | VAF 328/664 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs759610249, COSV55905466; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 294/642 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 195/407 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.330_332del p.K111del | In Frame Del (DEL) | VAF 23/47 reads (49%) | hotspot (GDC flag); called by mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 37/90 reads (41%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 556/557 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 22/486 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54387751, COSV54403101; called by muse, mutect2
- ADCY5 | c.3163C>T p.R1055C | Missense Mutation (SNP) | VAF 337/679 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs377330980; called by muse, mutect2, varscan2
- AHNAK2 | c.7886G>A p.R2629Q | Missense Mutation (SNP) | VAF 600/1227 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs572087329; called by muse, mutect2, varscan2
- ALK | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 278/582 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs769061878, COSV66555598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANTKMT | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 359/736 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748118024; called by muse, mutect2, varscan2
- APC | c.4391_4394del p.E1464Vfs*8 | Frame Shift Del (DEL) | VAF 69/75 reads (92%) | catalogued as rs387906234; called by mutect2, pindel, varscan2
- APC2 | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 348/640 reads (54%) | SIFT tolerated (0.66); PolyPhen benign (0.04); catalogued as rs949864607; called by muse, mutect2, varscan2
- BAG4 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 312/313 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs774897872; called by muse, mutect2, varscan2
- BNC1 | c.2387T>G p.L796R | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs139607641, COSV61757499; called by muse, mutect2, varscan2
- BRDT | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.838); catalogued as rs1487473834; called by muse, mutect2, varscan2
- BTN3A1 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 122/450 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs773029993; called by muse, mutect2, varscan2
- BTN3A3 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 262/647 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs1411664379; called by muse, mutect2, varscan2
- CD200R1L | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142953807, COSV68004161; called by muse, mutect2
- CFAP58 | c.1674+2T>C p.X558_splice | Splice Site (SNP) | VAF 65/121 reads (54%) | catalogued as rs773414802; called by muse, mutect2, varscan2
- CHD6 | c.7345G>A p.E2449K | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs769331541, COSV64690068; called by muse, mutect2
- CNTN3 | c.1845A>C p.Q615H | Missense Mutation (SNP) | VAF 98/215 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV55161936, COSV99726459; called by muse, mutect2, varscan2
- CPS1 | c.4357C>T p.R1453W | Missense Mutation (SNP) | VAF 107/232 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs933813349, CM104561, COSV51806734; called by muse, mutect2, varscan2
- CSPG4 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs148728726, COSV104413993; called by muse, mutect2, varscan2
- CUL9 | c.2245G>A p.V749M | Missense Mutation (SNP) | VAF 458/1004 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs376469889; called by muse, mutect2, varscan2
- DBP | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 372/826 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV55337120; called by muse, mutect2, varscan2
- DOCK5 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs369802050; called by muse, mutect2, varscan2
- DSCAML1 | c.6181G>A p.A2061T (on ENST00000321322; = p.A2001T on NM_020693.4) | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs778403842, COSV100356106; called by muse, mutect2, varscan2
- ELAPOR2 | c.917A>G p.N306S (on ENST00000450689 / NM_001142749.3; = p.N139S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 234/235 reads (100%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs762692749; called by muse, mutect2, varscan2
- ELFN1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 339/773 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1448289526; called by muse, mutect2, varscan2
- EPPK1 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 259/848 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.533); catalogued as rs934671022; called by muse, mutect2, varscan2
- EXOSC10 | c.1460C>T p.T487M | Missense Mutation (SNP) | VAF 93/167 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs748350072, COSV58666686; called by muse, mutect2, varscan2
- FAM47A | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1224051046, COSV60497362; called by muse, mutect2, varscan2
- FAM47B | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 363/364 reads (100%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs1003154042, COSV61453303, COSV61453412; called by muse, mutect2, varscan2
- FBXO34 | c.1607C>A p.S536Y | Missense Mutation (SNP) | VAF 185/384 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV58256660; called by muse, mutect2, varscan2
- FBXO9 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 136/300 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs1290789368, COSV99762214; called by muse, mutect2, varscan2
- FGD6 | c.2221A>G p.T741A | Missense Mutation (SNP) | VAF 240/524 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1386408999; called by muse, mutect2, varscan2
- FNDC1 | c.3848C>T p.T1283M | Missense Mutation (SNP) | VAF 464/922 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as rs780449351, COSV51939560; called by muse, mutect2, varscan2
- FRY | c.4136C>T p.S1379L | Missense Mutation (SNP) | VAF 664/1297 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.322); catalogued as rs746244232, COSV100968782; called by muse, mutect2, varscan2
- GCGR | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 407/832 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs552010052, COSV68779776; called by muse, mutect2, varscan2
- GDF5 | c.149G>T p.R50M | Missense Mutation (SNP) | VAF 191/405 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); catalogued as COSV65502226; called by muse, mutect2, varscan2
- GLIPR2 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 290/664 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs949478315; called by muse, mutect2, varscan2
- GPR182 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 242/518 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs776962475, COSV55626621, COSV55627041; called by muse, mutect2, varscan2
- GRK1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 357/779 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371556611; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 49/132 reads (37%) | catalogued as rs754199513; called by mutect2, varscan2
- H2BC10 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 334/665 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.158); catalogued as rs751586556, COSV59952772; called by muse, mutect2, varscan2
- HHAT | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 176/359 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as rs777581246, COSV54802868; called by muse, mutect2, varscan2
- IFT46 | c.763C>T p.R255W (on ENST00000264021 / NM_001168618.2; = p.R306W on NM_020153.3) | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs782137705; called by muse, mutect2, varscan2
- ING1 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 133/276 reads (48%) | catalogued as COSV58168738, COSV58170541; called by muse, mutect2, varscan2
- ITGA5 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 168/418 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0.115); catalogued as rs369973451, COSV53217784; called by muse, mutect2
- ITGB7 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 20/744 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57237734; called by muse, mutect2
- LCE2A | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 378/832 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100909179; called by muse, mutect2, varscan2
- LILRB5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 466/998 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs923890744, COSV60259321; called by muse, mutect2, varscan2
- LPAR3 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 314/640 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs889787610, COSV65453028; called by muse, mutect2, varscan2
- LRAT | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 325/721 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs776906234; called by muse, mutect2, varscan2
- LRPPRC | c.1734G>A p.T578= | Splice Region (SNP) | VAF 273/619 reads (44%) | catalogued as rs201889668; called by muse, mutect2, varscan2
- MARCO | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.198); catalogued as rs200590124; called by muse, mutect2, varscan2
- MINDY4 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 232/561 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.854); catalogued as rs764087591, COSV54675426; called by muse, mutect2, varscan2
- MPDZ | c.5113C>T p.R1705C | Missense Mutation (SNP) | VAF 155/312 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs529673809, COSV100058108; called by muse, mutect2, varscan2
- MPG | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 72/123 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as rs974375687; called by muse, mutect2, varscan2
- MPV17L | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 54/808 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs1445631252, COSV99806241; called by muse, mutect2
- MYBPC3 | c.2242G>A p.V748I | Missense Mutation (SNP) | VAF 243/592 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs730880563, COSV57033777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP5 | c.2011_2012del p.L671Vfs*6 | Frame Shift Del (DEL) | VAF 276/716 reads (39%) | catalogued as rs775483680; called by pindel, varscan2
- NR4A3 | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100432745; called by muse, mutect2, varscan2
- ODF1 | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 370/1289 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs755889668; called by muse, mutect2, varscan2
- OR2T34 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 178/843 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs746667499, COSV60899605, COSV60900803; called by muse, mutect2, varscan2
- PCDHGB2 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 600/1297 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs533999436; called by muse, mutect2, varscan2
- PCNX2 | c.4412G>A p.G1471D | Missense Mutation (SNP) | VAF 347/715 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV50874530; called by muse, mutect2, varscan2
- PDHA1 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 236/236 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100870313, COSV63328683; called by muse, mutect2, varscan2
- PIEZO2 | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 224/534 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1409494922; called by muse, mutect2, varscan2
- PKD1 | c.5527G>A p.G1843S | Missense Mutation (SNP) | VAF 371/745 reads (50%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as rs367732509; called by muse, mutect2, varscan2
- PRDM1 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 30/510 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); catalogued as rs777002137; called by muse, mutect2
- PRRC2B | c.3379C>T p.R1127* | Nonsense Mutation (SNP) | VAF 72/142 reads (51%) | catalogued as rs1300991170; called by muse, mutect2, varscan2
- RALB | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 173/392 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs141928830; called by muse, mutect2, varscan2
- RBFOX1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1236617150, COSV60955885, COSV60960221; called by muse, mutect2, varscan2
- SAFB | c.2432G>A p.R811Q | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.652); catalogued as rs773646650; called by muse, mutect2
- SALL3 | c.1318C>A p.R440S | Missense Mutation (SNP) | VAF 286/286 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73306627; called by muse, mutect2, varscan2
- SIPA1L1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1401169832; called by muse, mutect2, varscan2
- SLC22A13 | c.1075G>A p.G359S | Missense Mutation (SNP) | VAF 269/547 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528880884; called by muse, mutect2, varscan2
- SLC25A29 | c.305C>T p.A102V (on ENST00000359232 / NM_001039355.3; = p.A36V on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/721 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765370572, COSV63651082; called by muse, mutect2
- SLC27A1 | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 207/386 reads (54%) | catalogued as rs762073668; called by muse, mutect2, varscan2
- SLC6A1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 264/619 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV55114842; called by muse, mutect2, varscan2
- SLFNL1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 98/198 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs760307090; called by muse, mutect2, varscan2
- SMAD4 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 226/226 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs794726995, COSV61684489; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOX1 | c.672_683del p.H225_P228del | In Frame Del (DEL) | VAF 190/307 reads (62%) | catalogued as rs915453765; called by mutect2, varscan2
- SOX9 | c.1145_1146dup p.T383* | Frame Shift Ins (INS) | VAF 204/288 reads (71%) | catalogued as COSV55426030; called by mutect2, pindel, varscan2
- SPIRE1 | c.1561C>T p.R521* (on ENST00000409402 / NM_001128626.2; = p.R507* on NM_020148.3) | Nonsense Mutation (SNP) | VAF 228/484 reads (47%) | catalogued as rs747265516, COSV59152682; called by muse, mutect2, varscan2
- SPON1 | c.2033C>G p.S678W | Missense Mutation (SNP) | VAF 250/468 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59965501; called by muse, mutect2, varscan2
- TACR3 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 331/761 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as rs201938668, COSV100510776; called by muse, mutect2, varscan2
- TM7SF3 | c.933del p.F311Lfs*13 | Frame Shift Del (DEL) | VAF 49/130 reads (38%) | catalogued as rs778819221; called by mutect2, pindel, varscan2
- TRANK1 | c.2596C>T p.R866* | Nonsense Mutation (SNP) | VAF 238/518 reads (46%) | catalogued as rs535417879, COSV100084941; called by muse, mutect2, varscan2
- TRPM8 | c.2624C>G p.A875G | Missense Mutation (SNP) | VAF 119/235 reads (51%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV61222211; called by muse, mutect2, varscan2
- TUSC3 | c.797T>A p.V266E | Missense Mutation (SNP) | VAF 92/92 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs1345389131; called by muse, mutect2, varscan2
- UHRF2 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.94); PolyPhen benign (0.053); catalogued as rs371780891; called by muse, mutect2, varscan2
- ZIK1 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 208/429 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100277632; called by muse, mutect2, varscan2
- ZNF624 | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 51/51 reads (100%) | catalogued as rs754763390; called by muse, mutect2, varscan2
- ABCA12 | c.6665T>A p.F2222Y (on ENST00000272895 / NM_173076.3; = p.F1904Y on NM_015657.3) | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADAMTS16 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 236/527 reads (45%) | called by muse, mutect2, varscan2
- ARMH4 | c.478A>C p.K160Q | Missense Mutation (SNP) | VAF 121/239 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- BCL9L | c.4374_4377del p.L1459Wfs*97 | Frame Shift Del (DEL) | VAF 70/170 reads (41%) | called by mutect2, pindel, varscan2
- C2CD2L | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 447/897 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAND2 | c.662G>A p.R221Q (on ENST00000456430 / NM_001162499.2; = p.R128Q on NM_012298.3) | Missense Mutation (SNP) | VAF 424/848 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CATSPERE | c.1867G>A p.V623M | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CTXN3 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 201/378 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CYP21A2 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 1284/1291 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, varscan2
- DND1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 508/508 reads (100%) | SIFT tolerated (0.66); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EFCAB5 | c.2201C>G p.T734R | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ELMO2 | c.2153A>G p.H718R | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2
- EPHA3 | c.2735C>A p.T912N | Missense Mutation (SNP) | VAF 138/294 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- EPHA5 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM20B | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 21/406 reads (5%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); called by muse, mutect2
- FAM47B | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- FARP1 | c.2446G>T p.E816* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- FAT4 | c.5870T>A p.L1957Q | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- FMO5 | c.235T>G p.Y79D | Missense Mutation (SNP) | VAF 105/235 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FZD7 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 470/934 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GOLGA8R | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 85/372 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, varscan2
- HDGFL3 | c.220A>C p.K74Q | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIC2 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.321); called by muse, mutect2
- HNRNPD | c.104_105del p.Q35Rfs*34 | Frame Shift Del (DEL) | VAF 343/879 reads (39%) | called by mutect2, pindel, varscan2
- JAG1 | c.3350A>G p.E1117G | Missense Mutation (SNP) | VAF 188/381 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KCNC3 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 147/261 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KDM4B | c.1868C>A p.P623Q | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLC1 | c.1489-4A>G | Splice Region (SNP) | VAF 132/264 reads (50%) | called by muse, mutect2, varscan2
- LSM14A | c.1053_1054insTTGCC p.D352Lfs*42 | Frame Shift Ins (INS) | VAF 57/157 reads (36%) | called by mutect2, pindel, varscan2
- MAST1 | c.2548G>T p.A850S | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPND | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MUTYH | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 497/1414 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH9 | c.340T>C p.S114P | Missense Mutation (SNP) | VAF 357/756 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRK | c.2902G>T p.D968Y | Missense Mutation (SNP) | VAF 87/87 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- OAS1 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 31/636 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- OR2T10 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 186/800 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- OR52E6 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
- OR8B2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 155/453 reads (34%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.028); called by muse, mutect2
- OR9Q2 | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- PABPC4 | c.697T>A p.F233I | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH10 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PCDHB16 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 136/297 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PCGF6 | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 48/108 reads (44%) | called by muse, mutect2, varscan2
- PCNX3 | c.2645C>T p.P882L | Missense Mutation (SNP) | VAF 412/924 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- PIP5K1C | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 309/674 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRDM15 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 199/522 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRRC2B | c.6323C>A p.A2108D | Missense Mutation (SNP) | VAF 337/750 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RIMS1 | c.3875C>G p.T1292R | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SEPSECS | c.961G>C p.D321H | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETMAR | c.910_911del p.L304Vfs*14 | Frame Shift Del (DEL) | VAF 102/414 reads (25%) | called by pindel, varscan2
- SHANK1 | c.5708A>G p.D1903G | Missense Mutation (SNP) | VAF 195/439 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SIN3A | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SLC39A10 | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 115/232 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLC45A3 | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 374/745 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ST3GAL1 | c.542T>G p.V181G | Missense Mutation (SNP) | VAF 269/409 reads (66%) | PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SYNE1 | c.8183_8184insG p.E2729Rfs*5 (on ENST00000367255 / NM_182961.4; = p.E2736Rfs*5 on NM_033071.3) | Frame Shift Ins (INS) | VAF 115/286 reads (40%) | called by mutect2, pindel*, varscan2
- SYNE1 | c.3438A>C p.Q1146H (on ENST00000367255 / NM_182961.4; = p.Q1153H on NM_033071.3) | Missense Mutation (SNP) | VAF 240/521 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TAF5L | c.1628dup p.Y543* | Nonsense Mutation (INS) | VAF 318/853 reads (37%) | called by mutect2, pindel, varscan2
- TATDN2 | c.1324T>C p.S442P | Missense Mutation (SNP) | VAF 237/463 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMTC4 | c.2065C>A p.H689N (on ENST00000376234 / NM_001350577.2; = p.H708N on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TNNI1 | c.282T>G p.I94M | Missense Mutation (SNP) | VAF 98/214 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- TNPO1 | c.480del p.Q161Rfs*11 | Frame Shift Del (DEL) | VAF 81/243 reads (33%) | called by mutect2, pindel, varscan2
- XRCC1 | c.1829G>T p.R610L | Missense Mutation (SNP) | VAF 156/317 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ZNF25 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.289); called by muse, mutect2
- AGO4 | c.2007C>T p.Y669= | Silent (SNP) | VAF 151/287 reads (53%) | catalogued as COSV100942936; called by muse, mutect2, varscan2
- AMER2 | c.372C>T p.R124= | Silent (SNP) | VAF 57/89 reads (64%) | catalogued as rs1340350359, COSV100766199; called by muse, mutect2, varscan2
- ARHGEF26 | c.954C>T p.R318= | Silent (SNP) | VAF 447/1034 reads (43%) | called by muse, mutect2, varscan2
- ASPG | c.1248G>A p.A416= | Silent (SNP) | VAF 129/784 reads (16%) | catalogued as rs151283874; called by muse, mutect2, varscan2
- BNC1 | c.2712T>C p.D904= | Silent (SNP) | VAF 263/488 reads (54%) | catalogued as rs143642352, COSV100597560; called by muse, mutect2, varscan2
- BSN | c.3000C>A p.S1000= | Silent (SNP) | VAF 276/635 reads (43%) | catalogued as COSV56514059; called by muse, mutect2, varscan2
- CACNA2D3 | c.1662T>C p.Y554= | Silent (SNP) | VAF 114/231 reads (49%) | called by muse, mutect2, varscan2
- CAND2 | c.3645C>T p.A1215= (on ENST00000456430 / NM_001162499.2; = p.A1098= on NM_012298.3) | Silent (SNP) | VAF 300/708 reads (42%) | called by muse, mutect2, varscan2
- CCL4 | c.12C>T p.C4= | Silent (SNP) | VAF 62/996 reads (6%) | catalogued as rs199619169; called by muse, mutect2
- CLEC18B | c.858C>T p.Y286= | Silent (SNP) | VAF 80/379 reads (21%) | catalogued as rs774779300; called by muse, mutect2, varscan2
- CNTNAP4 | c.2445G>A p.A815= | Silent (SNP) | VAF 100/197 reads (51%) | catalogued as rs1291873267, COSV56697688; called by muse, mutect2, varscan2
- CTSF | c.228G>A p.S76= | Silent (SNP) | VAF 35/393 reads (9%) | called by muse, mutect2
- EHD2 | c.645C>T p.R215= | Silent (SNP) | VAF 156/338 reads (46%) | catalogued as rs1043214730, COSV54411427; called by muse, mutect2, varscan2
- EZHIP | c.615C>T p.H205= | Silent (SNP) | VAF 254/255 reads (100%) | catalogued as rs781928344; called by muse, mutect2, varscan2
- FERD3L | c.417G>T p.R139= | Silent (SNP) | VAF 366/720 reads (51%) | called by muse, mutect2, varscan2
- FN1 | c.3063G>A p.R1021= | Silent (SNP) | VAF 145/299 reads (48%) | called by muse, mutect2, varscan2
- GABBR2 | c.702C>T p.N234= | Silent (SNP) | VAF 257/582 reads (44%) | catalogued as rs759372813, COSV52316761; called by muse, mutect2, varscan2
- GRID1 | c.2244C>T p.Y748= | Silent (SNP) | VAF 308/639 reads (48%) | catalogued as rs543588600; called by muse, mutect2, varscan2
- GUCY1A2 | c.939T>C p.P313= | Silent (SNP) | VAF 168/333 reads (50%) | catalogued as COSV99977053; called by muse, mutect2, varscan2
- HEY2 | c.804C>T p.A268= | Silent (SNP) | VAF 163/361 reads (45%) | catalogued as COSV100856275, COSV64240839; called by muse, mutect2, varscan2
- HLTF | c.982C>T p.L328= | Silent (SNP) | VAF 43/82 reads (52%) | called by muse, mutect2, varscan2
- HOXA13 | c.948C>A p.A316= | Silent (SNP) | VAF 253/575 reads (44%) | called by muse, mutect2, varscan2
- ITGA4 | c.105C>T p.N35= | Silent (SNP) | VAF 309/692 reads (45%) | catalogued as rs1186977900, COSV52003081; called by muse, mutect2, varscan2
- KLHL21 | c.1488G>A p.P496= | Silent (SNP) | VAF 217/475 reads (46%) | catalogued as rs370458102; called by muse, mutect2, varscan2
- LAMA1 | c.3288G>T p.G1096= | Silent (SNP) | VAF 42/1160 reads (4%) | catalogued as COSV67531559; called by muse, mutect2
- LIMD1 | c.1050G>C p.P350= | Silent (SNP) | VAF 385/912 reads (42%) | called by muse, mutect2, varscan2
- LRCH2 | c.333G>A p.T111= | Silent (SNP) | VAF 79/80 reads (99%) | catalogued as COSV100407310; called by muse, mutect2, varscan2
- MLNR | c.1017C>T p.V339= | Silent (SNP) | VAF 332/729 reads (46%) | called by muse, mutect2, varscan2
- OLFM4 | c.816T>C p.G272= | Silent (SNP) | VAF 30/326 reads (9%) | called by muse, mutect2
- OR2A14 | c.771G>A p.T257= | Silent (SNP) | VAF 570/572 reads (100%) | catalogued as COSV68718293, COSV68718667; called by muse, mutect2, varscan2
- PCDH10 | c.1326G>A p.A442= | Silent (SNP) | VAF 208/418 reads (50%) | catalogued as COSV52101927; called by muse, mutect2, varscan2
- PRRT2 | c.987C>T p.I329= | Silent (SNP) | VAF 95/172 reads (55%) | catalogued as rs368411419, COSV54884812; called by muse, mutect2, varscan2
- PTP4A3 | c.312C>T p.C104= | Silent (SNP) | VAF 479/743 reads (64%) | catalogued as rs150025897; called by muse, mutect2, varscan2
- RAB8A | c.561G>A p.Q187= | Silent (SNP) | VAF 262/555 reads (47%) | catalogued as COSV99507113; called by muse, mutect2, varscan2
- ROPN1B | c.45G>A p.P15= | Silent (SNP) | VAF 248/478 reads (52%) | catalogued as COSV52542902, COSV52543324; called by muse, mutect2, varscan2
- RYR1 | c.879C>T p.T293= | Silent (SNP) | VAF 477/961 reads (50%) | catalogued as rs371599963; ClinVar: likely benign; called by muse, mutect2, varscan2
- SRSF11 | c.393G>A p.V131= | Silent (SNP) | VAF 149/296 reads (50%) | called by muse, mutect2, varscan2
- STK25 | c.930G>A p.A310= | Silent (SNP) | VAF 99/185 reads (54%) | catalogued as rs370416984; called by muse, mutect2, varscan2
- TBC1D1 | c.2016G>A p.P672= | Silent (SNP) | VAF 246/521 reads (47%) | catalogued as rs1373145747; called by muse, mutect2, varscan2
- TRIM9 | c.291C>T p.N97= | Silent (SNP) | VAF 61/124 reads (49%) | catalogued as rs1464157944; called by muse, mutect2
- TTBK2 | c.2883A>G p.P961= | Silent (SNP) | VAF 92/92 reads (100%) | catalogued as rs757518859; called by muse, mutect2, varscan2
- UNC80 | c.2700C>T p.I900= | Silent (SNP) | VAF 104/240 reads (43%) | catalogued as rs995706379, COSV55899628; called by muse, mutect2, varscan2
- WDR25 | c.831C>T p.N277= | Silent (SNP) | VAF 369/840 reads (44%) | catalogued as rs758971019, COSV58939543; called by muse, mutect2, varscan2
- WDR64 | c.1110C>T p.A370= | Silent (SNP) | VAF 123/290 reads (42%) | catalogued as rs142859030; called by muse, mutect2, varscan2
- ZFHX4 | c.9000C>T p.G3000= | Silent (SNP) | VAF 240/364 reads (66%) | catalogued as rs1183735569, COSV50565031; called by muse, mutect2, varscan2
- ZNF208 | c.873C>A p.G291= | Silent (SNP) | VAF 114/229 reads (50%) | called by muse, mutect2, varscan2
- ASXL1 | c.565+41C>T | Intron (SNP) | VAF 21/464 reads (5%) | called by muse, mutect2
- ATP6V0E1 | chr5:173020854 G>A | 3'Flank (SNP) | VAF 378/801 reads (47%) | called by muse, mutect2, varscan2
- CABIN1 | c.*25C>T | 3'UTR (SNP) | VAF 187/373 reads (50%) | catalogued as rs199716373, COSV99573202; called by muse, mutect2, varscan2
- CCNQ | c.*97C>T | 3'UTR (SNP) | VAF 492/492 reads (100%) | called by muse, mutect2, varscan2
- CLASP1 | c.196-649C>T | Intron (SNP) | VAF 76/161 reads (47%) | catalogued as rs774196943; called by muse, mutect2, varscan2
- CRYZ | c.631-27A>C | Intron (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- CYB561 | c.-13-512C>T | Intron (SNP) | VAF 141/268 reads (53%) | catalogued as rs1311622526, COSV62539520; called by muse, mutect2, varscan2
- EAF1 | c.-4G>A | 5'UTR (SNP) | VAF 433/964 reads (45%) | called by muse, mutect2, varscan2
- HEXA | c.1421+38G>A | Intron (SNP) | VAF 161/341 reads (47%) | called by muse, mutect2, varscan2
- MPPED1 | c.-52G>A | 5'UTR (SNP) | VAF 153/327 reads (47%) | called by muse, mutect2, varscan2
- POTEF | c.*4G>T | 3'UTR (SNP) | VAF 426/851 reads (50%) | called by muse, mutect2, varscan2
- SLC9A3 | c.-30G>A | 5'UTR (SNP) | VAF 40/77 reads (52%) | called by muse, mutect2, varscan2
- SYT14 | c.-6C>T | 5'UTR (SNP) | VAF 336/743 reads (45%) | called by muse, mutect2, varscan2
